Somatic mutation profile of tumor specimen TCGA-DK-A6B5-01A (aliquot TCGA-DK-A6B5-01A-11D-A31L-08) from TCGA case TCGA-DK-A6B5, project TCGA-BLCA (Bladder Urothelial Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Transitional cell carcinoma; Tissue or organ of origin: Anterior wall of bladder; AJCC pathologic stage: Stage IV; Tumor grade: High Grade; Age at diagnosis: 45.0 years (16,453 days).
Specimen TCGA-DK-A6B5-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) fce9f737-593f-44e1-aaf1-3412298b7d3e.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-DK-A6B5-10A (Blood Derived Normal), aliquot TCGA-DK-A6B5-10A-01D-A31J-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/fb9bd733-0bbd-4bb6-9ea5-e465180d87c4

The open-access MAF lists 149 somatic variants for this specimen: 106 protein-altering or splice-affecting, 38 silent, 5 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 92, Silent 38, Nonsense Mutation 9, Intron 3, Frame Shift Del 2, 5'UTR 1, RNA 1, Splice Site 1, In Frame Del 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BRCA2 | c.227C>G p.S76* | Nonsense Mutation (SNP) | VAF 26/97 reads (27%) | catalogued as rs80358498, COSV66452831; ClinVar: pathogenic; called by muse, mutect2, varscan2
- PIK3CA | c.1624G>A p.E542K | Missense Mutation (SNP) | VAF 37/66 reads (56%) | hotspot (GDC flag); SIFT deleterious (0.04); PolyPhen probably damaging (0.912); catalogued as rs121913273, CM153078, COSV55873227, COSV55894248; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- A2ML1 | c.1565T>G p.L522R | Missense Mutation (SNP) | VAF 50/149 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV55289443; called by muse, mutect2, varscan2
- ABCA8 | c.869C>G p.S290C | Missense Mutation (SNP) | VAF 38/84 reads (45%) | SIFT tolerated (0.06); PolyPhen benign (0.071); catalogued as rs1444074117, COSV52199701; called by muse, mutect2, varscan2
- ADNP | c.2301G>T p.R767S | Missense Mutation (SNP) | VAF 27/99 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV62425092; called by muse, mutect2, varscan2
- ALDH1A2 | c.65C>T p.S22L | Missense Mutation (SNP) | VAF 34/48 reads (71%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.015); catalogued as COSV51080145; called by muse, mutect2, varscan2
- AMER3 | c.1826C>G p.S609C | Missense Mutation (SNP) | VAF 43/132 reads (33%) | SIFT tolerated (0.07); PolyPhen benign (0.334); catalogued as COSV58466245; called by muse, mutect2, varscan2
- ARHGAP31 | c.956C>G p.S319* | Nonsense Mutation (SNP) | VAF 73/158 reads (46%) | catalogued as COSV99957112, COSV99957743; called by muse, mutect2, varscan2
- ARID1A | c.1355C>G p.P452R | Missense Mutation (SNP) | VAF 93/280 reads (33%) | SIFT tolerated, low confidence (0.07); PolyPhen possibly damaging (0.521); catalogued as COSV100252002, COSV61376016; called by muse, mutect2, varscan2
- ARID1A | c.1435C>T p.Q479* | Nonsense Mutation (SNP) | VAF 152/465 reads (33%) | catalogued as COSV61371604, COSV61372723; called by muse, mutect2, varscan2
- B4GALT4 | c.679C>T p.R227C | Missense Mutation (SNP) | VAF 86/160 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs777726655, COSV63295747; called by muse, mutect2, varscan2
- BCORL1 | c.3010C>G p.P1004A | Missense Mutation (SNP) | VAF 38/71 reads (54%) | SIFT deleterious (0.02); PolyPhen benign (0); catalogued as COSV54394789; called by muse, mutect2, varscan2
- BIRC2 | c.939G>C p.L313F | Missense Mutation (SNP) | VAF 14/327 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57160939, COSV57161173; called by muse, mutect2
- BPIFB4 | c.1097C>A p.S366Y | Missense Mutation (SNP) | VAF 51/102 reads (50%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV64951068; called by muse, mutect2, varscan2
- BRPF1 | c.3121G>A p.E1041K | Missense Mutation (SNP) | VAF 25/223 reads (11%) | SIFT tolerated (0.48); PolyPhen benign (0.191); catalogued as COSV57352539; called by muse, mutect2, varscan2
- BRS3 | c.901T>G p.Y301D | Missense Mutation (SNP) | VAF 16/192 reads (8%) | SIFT tolerated (0.56); PolyPhen benign (0.045); catalogued as COSV65710898; called by muse, mutect2
- C2CD2 | c.1582G>A p.D528N | Missense Mutation (SNP) | VAF 28/72 reads (39%) | SIFT tolerated (0.07); PolyPhen benign (0.003); catalogued as rs1191631442, COSV61599265; called by muse, mutect2, varscan2
- CADPS2 | c.1891G>C p.D631H | Missense Mutation (SNP) | VAF 14/42 reads (33%) | SIFT deleterious (0); PolyPhen benign (0.444); catalogued as COSV100462794; called by muse, mutect2
- CALD1 | c.1386+1G>T p.X462_splice | Splice Site (SNP) | VAF 7/14 reads (50%) | catalogued as COSV100724241; called by muse, mutect2
- CD19 | c.1493C>A p.S498Y (on ENST00000324662 / NM_001178098.2; = p.S497Y on NM_001770.6) | Missense Mutation (SNP) | VAF 36/129 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV104410546, COSV61188375; called by muse, mutect2, varscan2
- COMP | c.403C>A p.P135T | Missense Mutation (SNP) | VAF 7/15 reads (47%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.99); catalogued as COSV99721435; called by muse, mutect2, varscan2
- COPB2 | c.1740G>C p.L580F | Missense Mutation (SNP) | VAF 26/98 reads (27%) | SIFT tolerated (0.36); PolyPhen benign (0.029); catalogued as COSV60812377; called by muse, mutect2, varscan2
- CXXC1 | c.286G>A p.E96K | Missense Mutation (SNP) | VAF 93/141 reads (66%) | SIFT deleterious (0.05); PolyPhen benign (0.069); catalogued as COSV53274098; called by muse, mutect2, varscan2
- CYP26A1 | c.300C>G p.I100M | Missense Mutation (SNP) | VAF 19/382 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.93); catalogued as COSV56417891; called by muse, mutect2
- CYP27C1 | c.625G>C p.E209Q | Missense Mutation (SNP) | VAF 29/74 reads (39%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.571); catalogued as COSV100080109, COSV58866680; called by muse, mutect2, varscan2
- CYP3A5 | c.1368C>G p.I456M | Missense Mutation (SNP) | VAF 32/106 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.716); catalogued as COSV56119580; called by muse, mutect2, varscan2
- DAAM2 | c.605G>C p.S202T | Missense Mutation (SNP) | VAF 40/107 reads (37%) | SIFT deleterious (0); PolyPhen benign (0.067); catalogued as rs1378966737, COSV51310813; called by muse, mutect2, varscan2
- DARS1 | c.169G>T p.D57Y | Missense Mutation (SNP) | VAF 53/197 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.615); catalogued as COSV51537755; called by muse, mutect2, varscan2
- DCTPP1 | c.292G>C p.D98H | Missense Mutation (SNP) | VAF 20/66 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60000473; called by muse, mutect2, varscan2
- DLK1 | c.262G>C p.D88H | Missense Mutation (SNP) | VAF 28/78 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.914); catalogued as COSV57991343; called by muse, mutect2, varscan2
- DMRT1 | c.54C>G p.H18Q | Missense Mutation (SNP) | VAF 9/22 reads (41%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.033); catalogued as rs1300040798, COSV66520892; called by muse, mutect2, varscan2
- DSCAM | c.2345T>C p.L782P | Missense Mutation (SNP) | VAF 31/116 reads (27%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.876); catalogued as COSV68025375, COSV68031117; called by muse, mutect2, varscan2
- DUOX2 | c.4374C>G p.F1458L | Missense Mutation (SNP) | VAF 31/65 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.923); catalogued as COSV66530594, COSV66531742; called by muse, mutect2, varscan2
- DUOX2 | c.4251C>G p.I1417M | Missense Mutation (SNP) | VAF 10/21 reads (48%) | SIFT tolerated (0.07); PolyPhen benign (0.37); catalogued as rs763971157, COSV66531749; called by muse, mutect2, varscan2
- EIF4G3 | c.4275G>C p.E1425D | Missense Mutation (SNP) | VAF 24/76 reads (32%) | SIFT tolerated (0.08); PolyPhen benign (0); catalogued as COSV51680227; called by muse, mutect2, varscan2
- EPHA3 | c.946G>A p.D316N | Missense Mutation (SNP) | VAF 70/219 reads (32%) | SIFT deleterious (0.02); PolyPhen benign (0.194); catalogued as COSV60702358; called by muse, varscan2
- F2RL3 | c.670G>T p.D224Y | Missense Mutation (SNP) | VAF 6/22 reads (27%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.902); catalogued as COSV50185398; called by muse, mutect2, varscan2
- F2RL3 | c.671A>T p.D224V | Missense Mutation (SNP) | VAF 6/23 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.617); catalogued as COSV50185408; called by muse, mutect2, varscan2
- FAM161A | c.1415T>A p.I472N | Missense Mutation (SNP) | VAF 21/61 reads (34%) | SIFT deleterious (0.03); PolyPhen benign (0.2); catalogued as COSV56765652; called by muse, mutect2, varscan2
- FAM83B | c.763C>G p.L255V | Missense Mutation (SNP) | VAF 25/63 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.698); catalogued as COSV60921447; called by muse, mutect2, varscan2
- FGD1 | c.755C>T p.P252L | Missense Mutation (SNP) | VAF 11/17 reads (65%) | SIFT tolerated (0.09); PolyPhen benign (0); catalogued as COSV100911071; called by muse, mutect2, varscan2
- FZD10 | c.1044A>T p.E348D | Missense Mutation (SNP) | VAF 20/72 reads (28%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.995); catalogued as COSV57473293; called by muse, varscan2
- GAPDH | c.163A>G p.K55E | Missense Mutation (SNP) | VAF 9/123 reads (7%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.886); catalogued as COSV57520899; called by muse, mutect2
- GPSM2 | c.1123C>G p.L375V | Missense Mutation (SNP) | VAF 12/37 reads (32%) | SIFT tolerated (0.15); PolyPhen benign (0.08); catalogued as rs113407652, COSV51442192; called by muse, mutect2, varscan2
- GTF3C1 | c.4139C>T p.S1380L | Missense Mutation (SNP) | VAF 39/126 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.942); catalogued as rs1458599433, COSV62240588; called by muse, mutect2, varscan2
- H2BC11 | c.39G>C p.K13N | Missense Mutation (SNP) | VAF 62/166 reads (37%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.369); catalogued as rs201335271, COSV60361995, COSV60362652; called by muse, mutect2, varscan2
- H4C1 | c.217T>C p.Y73H | Missense Mutation (SNP) | VAF 31/86 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV55119264; called by muse, mutect2, varscan2
- HACL1 | c.862C>G p.H288D | Missense Mutation (SNP) | VAF 35/120 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58254224; called by muse, mutect2, varscan2
- HOXB2 | c.588G>A p.M196I | Missense Mutation (SNP) | VAF 36/108 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.946); catalogued as COSV57486583; called by muse, mutect2, varscan2
- HSPA1L | c.230G>A p.G77D | Missense Mutation (SNP) | VAF 60/165 reads (36%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.966); catalogued as COSV65149005; called by muse, mutect2, varscan2
- IGFBP1 | c.553G>A p.E185K | Missense Mutation (SNP) | VAF 22/32 reads (69%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.665); catalogued as rs1430137720, COSV51874550, COSV99298653, COSV99298719; called by muse, mutect2, varscan2
- KAT6A | c.5788C>T p.P1930S | Missense Mutation (SNP) | VAF 65/96 reads (68%) | SIFT deleterious, low confidence (0.04); PolyPhen probably damaging (0.996); catalogued as COSV55905328; called by muse, mutect2, varscan2
- KDM6A | c.3369_3370insTA p.H1124Yfs*7 | Frame Shift Ins (INS) | VAF 8/18 reads (44%) | catalogued as COSV65039599; called by mutect2, varscan2
- KLK14 | c.563T>C p.V188A | Missense Mutation (SNP) | VAF 19/420 reads (5%) | SIFT deleterious (0.01); PolyPhen benign (0.284); catalogued as COSV50068336; called by muse, mutect2
- KLK5 | c.728G>A p.G243D | Missense Mutation (SNP) | VAF 14/52 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1225635244, COSV60449661; called by muse, mutect2
- KPNB1 | c.195G>C p.L65F | Missense Mutation (SNP) | VAF 12/71 reads (17%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.855); catalogued as COSV51596526; called by muse, mutect2, varscan2
- KRT36 | c.1352G>A p.R451K | Missense Mutation (SNP) | VAF 25/96 reads (26%) | SIFT tolerated (0.91); PolyPhen benign (0); catalogued as rs1367979651, COSV60203151; called by muse, mutect2, varscan2
- LCOR | c.2290A>C p.S764R | Missense Mutation (SNP) | VAF 117/280 reads (42%) | SIFT tolerated (0.52); PolyPhen benign (0.005); catalogued as COSV53715450; called by muse, mutect2, varscan2
- LIPH | c.179C>A p.S60* | Nonsense Mutation (SNP) | VAF 100/237 reads (42%) | catalogued as CM156807, COSV56183486, COSV99955996; called by muse, mutect2, varscan2
- LRGUK | c.1621G>C p.E541Q | Missense Mutation (SNP) | VAF 59/158 reads (37%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.94); catalogued as COSV53637053, COSV53642813, COSV53644111; called by muse, mutect2, varscan2
- LRRC4C | c.869T>G p.L290W | Missense Mutation (SNP) | VAF 63/173 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53423445; called by muse, mutect2, varscan2
- METTL3 | c.1546G>A p.E516K | Missense Mutation (SNP) | VAF 33/47 reads (70%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52968467; called by muse, mutect2, varscan2
- MYF6 | c.427C>T p.R143W | Missense Mutation (SNP) | VAF 37/88 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.907); catalogued as COSV57351382; called by muse, mutect2, varscan2
- NADK2 | c.278C>A p.S93* | Nonsense Mutation (SNP) | VAF 17/30 reads (57%) | catalogued as COSV99237520; called by muse, mutect2, varscan2
- NDST4 | c.391G>A p.V131I | Missense Mutation (SNP) | VAF 19/28 reads (68%) | SIFT tolerated (1); PolyPhen benign (0.006); catalogued as COSV52116728; called by muse, mutect2, varscan2
- NELL2 | c.352A>G p.S118G | Missense Mutation (SNP) | VAF 8/149 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.794); catalogued as COSV61573239; called by muse, mutect2
- ORC3 | c.539C>T p.S180L | Missense Mutation (SNP) | VAF 26/47 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.926); catalogued as COSV57639052; called by muse, mutect2, varscan2
- OXNAD1 | c.21G>A p.M7I | Missense Mutation (SNP) | VAF 62/255 reads (24%) | SIFT tolerated, low confidence (0.37); PolyPhen benign (0); catalogued as COSV53266480; called by muse, mutect2, varscan2
- OXNAD1 | c.145G>A p.D49N | Missense Mutation (SNP) | VAF 28/141 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.941); catalogued as COSV53266501; called by muse, varscan2
- PABPC3 | c.52C>T p.L18F | Missense Mutation (SNP) | VAF 18/145 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1395331668, COSV55799668; called by muse, mutect2, varscan2
- PCDH11Y | c.2785G>T p.D929Y (on ENST00000400457 / NM_032973.2; = p.D918Y on NM_032971.3) | Missense Mutation (SNP) | VAF 60/609 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.722); catalogued as COSV53079224; called by muse, mutect2
- PLCG1 | c.3381G>C p.K1127N | Missense Mutation (SNP) | VAF 24/54 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as COSV54817781; called by muse, mutect2, varscan2
- PLK3 | c.307C>T p.Q103* | Nonsense Mutation (SNP) | VAF 22/51 reads (43%) | catalogued as rs775565518, COSV100221159, COSV59500657; called by muse, mutect2, varscan2
- POLD1 | c.394G>A p.D132N | Missense Mutation (SNP) | VAF 43/124 reads (35%) | SIFT tolerated (0.1); PolyPhen benign (0.022); catalogued as rs781132734, COSV70954916; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- POU3F3 | c.1090G>C p.E364Q | Missense Mutation (SNP) | VAF 39/139 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV63721611; called by muse, mutect2, varscan2
- POU6F2 | c.65G>A p.R22Q | Missense Mutation (SNP) | VAF 19/27 reads (70%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.003); catalogued as rs775326639, COSV68872282; called by muse, mutect2, varscan2
- PPP1R3A | c.511G>A p.D171N | Missense Mutation (SNP) | VAF 18/44 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52880850, COSV52883284; called by muse, mutect2, varscan2
- PTCD3 | c.427G>C p.E143Q | Missense Mutation (SNP) | VAF 30/90 reads (33%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.981); catalogued as COSV54479726; called by muse, mutect2, varscan2
- RAD50 | c.3529G>C p.D1177H | Missense Mutation (SNP) | VAF 40/60 reads (67%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.814); catalogued as COSV54750481; called by muse, mutect2, varscan2
- RIOX2 | c.58A>G p.K20E | Missense Mutation (SNP) | VAF 20/50 reads (40%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.988); catalogued as COSV57724102; called by muse, mutect2, varscan2
- RSPRY1 | c.1270G>C p.E424Q | Missense Mutation (SNP) | VAF 5/62 reads (8%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.863); catalogued as COSV101071014; called by muse, mutect2
- SIGLEC12 | c.548C>G p.S183C (on ENST00000291707 / NM_053003.4; = p.S65C on NM_033329.2) | Missense Mutation (SNP) | VAF 52/155 reads (34%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.962); catalogued as rs774688289, COSV52460942; called by muse, mutect2, varscan2
- SIRT1 | c.1948T>G p.Y650D | Missense Mutation (SNP) | VAF 10/94 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); catalogued as COSV53017870; called by muse, mutect2
- SLC39A7 | c.665G>C p.W222S | Missense Mutation (SNP) | VAF 46/119 reads (39%) | SIFT deleterious (0.05); PolyPhen benign (0.093); catalogued as COSV63399663; called by muse, mutect2, varscan2
- SMCR8 | c.736C>A p.H246N | Missense Mutation (SNP) | VAF 23/46 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1399707205, COSV58176805; called by muse, mutect2, varscan2
- SPAG5 | c.1453C>T p.Q485* | Nonsense Mutation (SNP) | VAF 30/80 reads (38%) | catalogued as rs768491191, COSV100410672; called by muse, mutect2, varscan2
- SPTAN1 | c.3576G>A p.W1192* | Nonsense Mutation (SNP) | VAF 17/36 reads (47%) | catalogued as COSV100823570; called by muse, mutect2, varscan2
- STRN3 | c.1847A>C p.Q616P (on ENST00000357479 / NM_001083893.2; = p.Q532P on NM_014574.4) | Missense Mutation (SNP) | VAF 30/49 reads (61%) | SIFT tolerated (0.33); PolyPhen benign (0); catalogued as rs780342567, COSV62579269; called by muse, mutect2, varscan2
- TBC1D5 | c.1499C>T p.S500L | Missense Mutation (SNP) | VAF 26/44 reads (59%) | SIFT tolerated (0.36); PolyPhen benign (0); catalogued as COSV53754660; called by muse, mutect2, varscan2
- TBC1D8B | c.965T>C p.I322T | Missense Mutation (SNP) | VAF 11/68 reads (16%) | SIFT tolerated (0.55); PolyPhen benign (0.24); catalogued as COSV52178105; called by muse, mutect2, varscan2
- TEAD4 | c.124G>A p.V42M | Missense Mutation (SNP) | VAF 83/300 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs763254392, COSV63280733; called by muse, mutect2, varscan2
- TEX2 | c.443C>A p.P148H | Missense Mutation (SNP) | VAF 58/178 reads (33%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.781); catalogued as COSV51980275; called by muse, mutect2, varscan2
- THADA | c.3436A>C p.I1146L | Missense Mutation (SNP) | VAF 23/47 reads (49%) | SIFT deleterious (0.01); PolyPhen benign (0.377); catalogued as COSV57681901; called by muse, mutect2, varscan2
- TNRC6C | c.1890G>A p.W630* | Nonsense Mutation (SNP) | VAF 23/86 reads (27%) | catalogued as COSV100050006; called by muse, mutect2, varscan2
- TRIM13 | c.595G>A p.E199K | Missense Mutation (SNP) | VAF 16/41 reads (39%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.994); catalogued as COSV53949023; called by muse, mutect2, varscan2
- TRRAP | c.6550C>G p.P2184A (on ENST00000359863 / NM_001244580.1; = p.P2166A on NM_003496.3) | Missense Mutation (SNP) | VAF 52/144 reads (36%) | SIFT tolerated (0.14); PolyPhen benign (0.125); catalogued as rs1324520249, COSV62843025; called by muse, mutect2, varscan2
- TULP4 | c.436G>A p.D146N | Missense Mutation (SNP) | VAF 60/105 reads (57%) | SIFT deleterious (0.01); PolyPhen benign (0.003); catalogued as COSV65574650; called by muse, mutect2, varscan2
- UHRF1BP1L | c.2144del p.P715Qfs*2 | Frame Shift Del (DEL) | VAF 20/85 reads (24%) | catalogued as COSV54436575; called by pindel, varscan2*
- USP32 | c.4423G>A p.E1475K | Missense Mutation (SNP) | VAF 59/134 reads (44%) | SIFT tolerated, low confidence (0.42); PolyPhen benign (0.023); catalogued as rs1229077806, COSV56267567; called by muse, mutect2, varscan2
- VCAN | c.8389G>C p.D2797H | Missense Mutation (SNP) | VAF 51/88 reads (58%) | SIFT tolerated (0.26); PolyPhen benign (0); catalogued as COSV54103587; called by muse, mutect2, varscan2
- ZNF382 | c.455G>C p.R152T | Missense Mutation (SNP) | VAF 60/184 reads (33%) | SIFT tolerated (0.27); PolyPhen benign (0.247); catalogued as COSV53087762, COSV99497571; called by muse, mutect2, varscan2
- ZNF799 | c.545G>A p.G182E | Missense Mutation (SNP) | VAF 51/85 reads (60%) | SIFT tolerated (0.24); PolyPhen benign (0.105); catalogued as COSV70122369; called by muse, mutect2, varscan2
- ZNF800 | c.55G>A p.E19K | Missense Mutation (SNP) | VAF 21/66 reads (32%) | SIFT tolerated (0.18); PolyPhen benign (0.001); catalogued as COSV56175176; called by muse, mutect2, varscan2
- IGHV1OR15-9 | c.346G>T p.V116L | Missense Mutation (SNP) | VAF 45/268 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- LRP6 | c.77_115del p.A26_N38del | In Frame Del (DEL) | VAF 7/62 reads (11%) | called by mutect2, pindel
- TMEM260 | c.927_928del p.I309Mfs*69 | Frame Shift Del (DEL) | VAF 28/64 reads (44%) | called by pindel, varscan2
- CA11 | c.9T>G p.A3= | Silent (SNP) | VAF 6/18 reads (33%) | catalogued as COSV99320639; called by muse, mutect2, varscan2
- CHP1 | c.195G>T p.R65= | Silent (SNP) | VAF 26/51 reads (51%) | catalogued as COSV58156897; called by muse, mutect2, varscan2
- CKMT2 | c.372C>T p.D124= | Silent (SNP) | VAF 40/74 reads (54%) | catalogued as COSV54172946; called by muse, mutect2, varscan2
- CLN6 | c.417C>T p.F139= | Silent (SNP) | VAF 68/235 reads (29%) | catalogued as rs1286877190, COSV51116640; called by muse, mutect2, varscan2
- CLYBL | c.972G>T p.L324= | Silent (SNP) | VAF 25/148 reads (17%) | catalogued as COSV59220548; called by muse, mutect2, varscan2
- ELOA3C | c.633C>T p.L211= | Silent (SNP) | VAF 42/640 reads (7%) | catalogued as COSV55297674; called by muse, mutect2
- FRAT1 | c.708C>A p.L236= | Silent (SNP) | VAF 9/36 reads (25%) | catalogued as rs559217519, COSV64017437; called by muse, varscan2
- GBA2 | c.2157C>T p.L719= | Silent (SNP) | VAF 10/132 reads (8%) | catalogued as rs1229280022, COSV62305652; called by muse, mutect2
- H2BC5 | c.48G>A p.K16= | Silent (SNP) | VAF 57/175 reads (33%) | catalogued as COSV56800730; called by muse, mutect2, varscan2
- HIPK4 | c.1008C>T p.I336= | Silent (SNP) | VAF 43/103 reads (42%) | catalogued as COSV52520580; called by muse, mutect2, varscan2
- IGSF9 | c.216C>G p.L72= | Silent (SNP) | VAF 21/66 reads (32%) | catalogued as COSV63639769; called by muse, mutect2, varscan2
- IPO13 | c.1446C>G p.V482= | Silent (SNP) | VAF 44/145 reads (30%) | catalogued as COSV64893900, COSV64894157; called by muse, mutect2, varscan2
- KRT16 | c.858G>T p.L286= | Silent (SNP) | VAF 70/278 reads (25%) | catalogued as COSV56967696; called by muse, mutect2, varscan2
- MAGEB6 | c.1152C>T p.P384= | Silent (SNP) | VAF 80/104 reads (77%) | catalogued as rs143709838, COSV66872134; called by muse, mutect2, varscan2
- MYBPH | c.1413C>G p.V471= | Silent (SNP) | VAF 104/295 reads (35%) | catalogued as COSV55142157; called by muse, mutect2, varscan2
- MYO3A | c.2049T>C p.Y683= | Silent (SNP) | VAF 61/158 reads (39%) | catalogued as COSV56327842; called by muse, mutect2, varscan2
- MYO3A | c.3741G>A p.E1247= | Silent (SNP) | VAF 31/103 reads (30%) | catalogued as rs777162777, COSV56319635, COSV56327849; called by muse, mutect2, varscan2
- OR4K13 | c.441C>T p.S147= | Silent (SNP) | VAF 16/152 reads (11%) | catalogued as rs576745694, COSV59859455; called by muse, mutect2
- PDZD2 | c.7422C>T p.P2474= | Silent (SNP) | VAF 75/140 reads (54%) | catalogued as COSV56856514; called by muse, mutect2, varscan2
- PHAX | c.876C>G p.L292= | Silent (SNP) | VAF 9/14 reads (64%) | catalogued as COSV52550980, COSV99881535; called by muse, mutect2, varscan2
- PKHD1 | c.7896C>A p.I2632= | Silent (SNP) | VAF 52/150 reads (35%) | catalogued as COSV61871730; called by muse, mutect2, varscan2
- PPP2R5D | c.207C>T p.L69= | Silent (SNP) | VAF 65/209 reads (31%) | catalogued as COSV57839757; called by muse, mutect2, varscan2
- PRDM2 | c.4728C>T p.S1576= | Silent (SNP) | VAF 45/112 reads (40%) | catalogued as COSV52445590; called by muse, mutect2, varscan2
- RYR2 | c.14109G>A p.V4703= | Silent (SNP) | VAF 16/36 reads (44%) | catalogued as COSV63680377; called by muse, mutect2, varscan2
- RYR3 | c.2208G>A p.L736= | Silent (SNP) | VAF 16/30 reads (53%) | catalogued as COSV66785650; called by muse, mutect2, varscan2
- SETD5 | c.1467A>G p.P489= | Silent (SNP) | VAF 16/228 reads (7%) | catalogued as COSV56709966; called by muse, mutect2
- SLC45A3 | c.615C>T p.L205= | Silent (SNP) | VAF 19/39 reads (49%) | catalogued as COSV65654859; called by muse, mutect2, varscan2
- SLC9A2 | c.597C>T p.L199= | Silent (SNP) | VAF 125/323 reads (39%) | catalogued as COSV52130097; called by muse, mutect2, varscan2
- STX17 | c.393G>A p.L131= | Silent (SNP) | VAF 22/37 reads (59%) | catalogued as COSV52283443; called by muse, mutect2, varscan2
- TEX13B | c.828C>T p.L276= | Silent (SNP) | VAF 99/129 reads (77%) | catalogued as rs375765697, COSV57202575; called by muse, mutect2, varscan2
- TIE1 | c.1749C>T p.R583= | Silent (SNP) | VAF 39/84 reads (46%) | catalogued as COSV65249329; called by muse, mutect2, varscan2
- TNC | c.6081G>C p.L2027= | Silent (SNP) | VAF 62/92 reads (67%) | catalogued as COSV60783919; called by muse, mutect2, varscan2
- TNFAIP8L3 | c.516G>C p.V172= | Silent (SNP) | VAF 56/99 reads (57%) | catalogued as COSV59528521; called by muse, mutect2, varscan2
- UNC119B | c.513G>T p.R171= | Silent (SNP) | VAF 33/125 reads (26%) | catalogued as COSV60866134; called by muse, mutect2, varscan2
- UPF1 | c.2367G>T p.T789= (on ENST00000599848 / NM_001297549.2; = p.T778= on NM_002911.4) | Silent (SNP) | VAF 5/27 reads (19%) | catalogued as COSV53195650, COSV53197452; called by muse, mutect2, varscan2
- ZFY | c.1665C>T p.H555= | Silent (SNP) | VAF 51/303 reads (17%) | catalogued as COSV50083202; called by muse, mutect2, varscan2
- ZNF175 | c.1218C>G p.L406= | Silent (SNP) | VAF 31/97 reads (32%) | catalogued as COSV51795126; called by muse, mutect2, varscan2
- ZSCAN20 | c.252C>T p.I84= | Silent (SNP) | VAF 30/70 reads (43%) | catalogued as rs747019512, COSV63682376; called by muse, mutect2, varscan2
- ERCC6 | c.1397+8326A>T | Intron (SNP) | VAF 60/188 reads (32%) | catalogued as COSV63389485; called by muse, mutect2, varscan2
- OLFML2B | c.-1C>T | 5'UTR (SNP) | VAF 16/45 reads (36%) | catalogued as rs981215447, COSV54194423, COSV99668436; called by muse, mutect2, varscan2
- RPL27A | c.143+184T>A | Intron (SNP) | VAF 60/103 reads (58%) | catalogued as COSV100029965; called by muse, mutect2, varscan2
- STARD7-AS1 | n.1580G>A | RNA (SNP) | VAF 43/118 reads (36%) | called by muse, mutect2, varscan2
- TREX2 | c.-183+491C>T | Intron (SNP) | VAF 33/43 reads (77%) | catalogued as COSV57848023; called by muse, mutect2, varscan2
